Somatic mutation profile of tumor specimen MMRF_2352_1_BM_CD138pos (aliquot MMRF_2352_1_BM_CD138pos_T1_KHS5U_K13997) from MMRF case MMRF_2352, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 60.6 years (22,131 days).
Specimen MMRF_2352_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 92980f83-08d2-47e7-8630-d2cb5db11de7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2352_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2352_1_PB_Whole_C1_KHS5U_K13996; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fe080dc2-48c7-437c-b2a8-3ac39835b06e

The open-access MAF lists 66 somatic variants for this specimen: 31 protein-altering or splice-affecting, 3 silent, 32 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, 3'UTR 18, Intron 10, Silent 3, 5'UTR 2, Nonsense Mutation 2, Frame Shift Del 1, 3'Flank 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EPG5 | c.3152C>G p.S1051* | Nonsense Mutation (SNP) | VAF 63/148 reads (43%) | catalogued as rs746885334, COSV56351291; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.523C>G p.R175G | Missense Mutation (SNP) | VAF 51/105 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs138729528, CM011013, CM118880, COSV52688031, COSV52713177, COSV52717943, COSV53372849; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CCDC166 | c.1091C>T p.S364L | Missense Mutation (SNP) | VAF 69/158 reads (44%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.74); catalogued as rs781940688; called by muse, mutect2, varscan2
- CEMIP | c.413A>G p.Y138C | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as rs1379783375; called by muse, mutect2
- CYP4F12 | c.455C>T p.T152M | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as rs369172315; called by muse, mutect2, varscan2
- DNAH10 | c.6829G>A p.G2277R (on ENST00000409039; = p.G2216R on NM_207437.3) | Missense Mutation (SNP) | VAF 86/95 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1463111937, COSV101292209; called by muse, mutect2, varscan2
- ENTHD1 | c.148C>G p.L50V | Missense Mutation (SNP) | VAF 78/170 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV57318968; called by muse, mutect2, varscan2
- HDAC9 | c.875C>T p.S292L | Missense Mutation (SNP) | VAF 41/84 reads (49%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs866117915, COSV67773682; called by muse, mutect2, varscan2
- IGLV1-44 | c.175C>T p.L59F | Missense Mutation (SNP) | VAF 114/304 reads (38%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); catalogued as rs771836514; called by muse, varscan2
- IGLV1-44 | c.293T>C p.L98P | Missense Mutation (SNP) | VAF 67/137 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs1347831337; called by muse, mutect2, varscan2
- IGLV5-45 | c.155A>G p.Y52C | Missense Mutation (SNP) | VAF 77/206 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.134); catalogued as rs548588169; called by muse, varscan2
- MAGEL2 | c.2230G>A p.A744T | Missense Mutation (SNP) | VAF 62/135 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.018); catalogued as rs764011034, COSV58565968; called by muse, mutect2, varscan2
- OR51L1 | c.532C>A p.H178N | Missense Mutation (SNP) | VAF 80/186 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58624204; called by muse, mutect2, varscan2
- PCDHB14 | c.367G>A p.V123I | Missense Mutation (SNP) | VAF 120/276 reads (43%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.02); catalogued as COSV53391677; called by muse, mutect2, varscan2
- TRAF3 | c.1501C>T p.Q501* | Nonsense Mutation (SNP) | VAF 7/89 reads (8%) | catalogued as rs1245984654; called by muse, mutect2
- ANP32D | c.184A>C p.K62Q | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- ASPM | c.10234A>T p.M3412L | Missense Mutation (SNP) | VAF 12/17 reads (71%) | SIFT deleterious (0.04); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- CENPB | c.601T>A p.Y201N | Missense Mutation (SNP) | VAF 71/136 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CLTCL1 | c.4843G>A p.A1615T (on ENST00000427926 / NM_007098.4; = p.A1558T on NM_001835.4) | Missense Mutation (SNP) | VAF 67/126 reads (53%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DCHS1 | c.8069C>T p.A2690V | Missense Mutation (SNP) | VAF 4/80 reads (5%) | SIFT tolerated (0.57); PolyPhen benign (0.01); called by muse, mutect2
- DMXL2 | c.8540G>T p.S2847I | Missense Mutation (SNP) | VAF 44/97 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- IGLV7-43 | c.19T>C p.F7L | Missense Mutation (SNP) | VAF 107/183 reads (58%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MLKL | c.826C>T p.P276S | Missense Mutation (SNP) | VAF 68/123 reads (55%) | SIFT tolerated (0.47); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- PHC3 | c.742A>C p.N248H (on ENST00000494943 / NM_001308116.2; = p.N260H on NM_024947.4) | Missense Mutation (SNP) | VAF 98/206 reads (48%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- PITPNC1 | c.656C>T p.A219V | Missense Mutation (SNP) | VAF 55/210 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- SP9 | c.813C>A p.S271R | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- TRAF3 | c.967A>C p.I323L | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.94); PolyPhen benign (0); called by muse, varscan2
- TRAF3 | c.976_980del p.Q326Rfs*7 | Frame Shift Del (DEL) | VAF 19/66 reads (29%) | called by pindel, varscan2
- USP42 | c.695A>C p.Q232P | Missense Mutation (SNP) | VAF 135/304 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- VPREB1 | c.61C>T p.P21S | Missense Mutation (SNP) | VAF 120/268 reads (45%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- ZSCAN22 | c.1240G>A p.G414S | Missense Mutation (SNP) | VAF 151/290 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- NMUR2 | c.522C>T p.S174= | Silent (SNP) | VAF 44/82 reads (54%) | catalogued as COSV54916930; called by muse, mutect2, varscan2
- ZFHX4 | c.1086T>C p.G362= | Silent (SNP) | VAF 58/261 reads (22%) | called by muse, mutect2, varscan2
- ZNF687 | c.2145C>T p.P715= | Silent (SNP) | VAF 175/380 reads (46%) | called by muse, mutect2, varscan2
- ABLIM2 | c.1516+562G>A | Intron (SNP) | VAF 23/164 reads (14%) | catalogued as rs1230094587; called by muse, mutect2, varscan2
- ADCYAP1 | c.*734C>T | 3'UTR (SNP) | VAF 12/85 reads (14%) | called by muse, mutect2, varscan2
- ARHGAP35 | c.*869del | 3'UTR (DEL) | VAF 10/27 reads (37%) | called by mutect2, pindel, varscan2
- ATP5MC1 | c.39+74C>A | Intron (SNP) | VAF 6/21 reads (29%) | catalogued as rs1478931078; called by muse, mutect2, varscan2
- BCL10 | c.-228G>A | 5'UTR (SNP) | VAF 29/33 reads (88%) | called by muse, mutect2, varscan2
- C2CD2 | c.*2821A>T | 3'UTR (SNP) | VAF 33/75 reads (44%) | called by muse, mutect2, varscan2
- CHRNA9 | c.*570G>T | 3'UTR (SNP) | VAF 61/124 reads (49%) | called by muse, mutect2, varscan2
- CSNK1G2 | c.-266+12624C>T | Intron (SNP) | VAF 114/237 reads (48%) | called by muse, mutect2, varscan2
- DENND2A | c.2327+68G>A | Intron (SNP) | VAF 85/170 reads (50%) | called by muse, mutect2, varscan2
- DNAJC27 | c.240+44T>G | Intron (SNP) | VAF 79/159 reads (50%) | called by muse, mutect2, varscan2
- FAM162A | c.*924G>A | 3'UTR (SNP) | VAF 17/25 reads (68%) | called by muse, mutect2, varscan2
- FSD2 | c.*2801_*2802del | 3'UTR (DEL) | VAF 30/77 reads (39%) | called by mutect2, pindel, varscan2
- GRIK2 | c.1748+26T>A | Intron (SNP) | VAF 176/193 reads (91%) | called by muse, mutect2, varscan2
- ISY1 | c.419-2207C>A | Intron (SNP) | VAF 4/14 reads (29%) | called by muse, mutect2
- LONRF2 | c.*9481A>G | 3'UTR (SNP) | VAF 6/94 reads (6%) | called by muse, mutect2
- NBPF3 | c.*323T>G | 3'UTR (SNP) | VAF 4/24 reads (17%) | catalogued as rs200265424; called by muse, mutect2
- OGDHL | c.*124C>A | 3'UTR (SNP) | VAF 39/127 reads (31%) | called by muse, mutect2
- PAPPA2 | c.*2177T>A | 3'UTR (SNP) | VAF 35/58 reads (60%) | called by muse, mutect2
- PAX9 | c.*675G>C | 3'UTR (SNP) | VAF 37/43 reads (86%) | called by muse, mutect2, varscan2
- PCDH11X | c.-449C>T | 5'UTR (SNP) | VAF 12/200 reads (6%) | called by muse, mutect2
- PDE5A | c.*1994T>A | 3'UTR (SNP) | VAF 27/110 reads (25%) | called by muse, mutect2, varscan2
- PNPLA7 | c.2965-62G>A | Intron (SNP) | VAF 24/48 reads (50%) | called by muse, mutect2, varscan2
- RASGRF2 | c.*2247C>A | 3'UTR (SNP) | VAF 8/20 reads (40%) | called by muse, mutect2
- RIC8A | c.*731C>T | 3'UTR (SNP) | VAF 16/44 reads (36%) | called by muse, mutect2, varscan2
- RPS6KA3 | c.*4412T>C | 3'UTR (SNP) | VAF 25/31 reads (81%) | called by muse, mutect2, varscan2
- SBK2 | chr19:55529652 A>G | 3'Flank (SNP) | VAF 65/120 reads (54%) | called by muse, mutect2, varscan2
- SCARB2 | c.*1957C>T | 3'UTR (SNP) | VAF 16/32 reads (50%) | called by muse, mutect2, varscan2
- SLC30A4 | c.391+1032C>A | Intron (SNP) | VAF 33/80 reads (41%) | called by muse, mutect2, varscan2
- SLC6A15 | c.756+396T>C | Intron (SNP) | VAF 55/62 reads (89%) | called by muse, mutect2, varscan2
- TMSB4X | chrX:12975430 G>A | 5'Flank (SNP) | VAF 69/70 reads (99%) | called by muse, mutect2, varscan2
- TRIM15 | c.*154_*157del | 3'UTR (DEL) | VAF 46/111 reads (41%) | catalogued as rs371041335; called by pindel, varscan2
- ZCCHC17 | c.*679G>A | 3'UTR (SNP) | VAF 39/72 reads (54%) | catalogued as rs922275160; called by muse, mutect2, varscan2
